Somatic mutation profile of tumor specimen 0DTC62 from CCDI case PBCJCA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Meningioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 15.1 years (5,506 days).
Specimen 0DTC62: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 23d5f17d-c633-4e27-a012-e7e586b3f822.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DTC5R (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5b5395b3-a927-41e0-a7cc-b1711dd03615

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Intron 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CELSR2 | c.4486G>A p.G1496R | Missense Mutation (SNP) | VAF 18/550 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1241327662; called by muse, mutect2
- ATP11C | c.1733A>G p.N578S | Missense Mutation (SNP) | VAF 326/1016 reads (32%) | SIFT tolerated (0.94); PolyPhen benign (0); called by muse, mutect2, varscan2
- C17orf80 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 42/1310 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.003); called by muse, mutect2
- DNAH5 | c.13060G>A p.A4354T | Missense Mutation (SNP) | VAF 58/852 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2
- MUC12 | c.11226C>T p.I3742= (on ENST00000379442; = p.I3599= on NM_001164462.1) | Silent (SNP) | VAF 50/554 reads (9%) | catalogued as rs1257720506; called by muse, varscan2
- CALCOCO2 | c.825+76T>A | Intron (SNP) | VAF 10/224 reads (4%) | called by muse, mutect2
- SOD2 | c.226+216A>T | Intron (SNP) | VAF 18/370 reads (5%) | called by muse, mutect2
